Gene-level copy-number profile of tumor specimen TCGA-MZ-A6I9-01A from TCGA case TCGA-MZ-A6I9, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Oropharynx, NOS; Tumor grade: G2; Age at diagnosis: 68.3 years (24,939 days).
Specimen TCGA-MZ-A6I9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.d5c9d7a8-5350-4743-8413-2f8d863b1465.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MZ-A6I9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bc5903b2-2a73-494e-9269-c6c7e87e7059

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9,127; copy number 2: 46,172; copy number 3: 2,665; copy number 5: 1,805; copy number 9: 46.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MZ-A6I9-01A-11D-A31K-01): tumor purity 0.37, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,851 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:91,356,755–198,222,513, 1,802 genes, copy number 5 (broad region; genes not listed).
- chr11:42,939,775–44,932,423, 46 genes, copy number 9 (within-gene range 2–9): AC109810.1, AC009643.2, AC009643.1, HNRNPKP3, API5, AC087276.2, Y_RNA, TTC17, AC087276.3, AC087276.1, RN7SKP287, PPIAP41, CTBP2P6, AC068205.1, MIR670, MIR670HG, AC068205.2, MIR129-2, HSD17B12, AC068205.3, RPL23AP63, PHBP2, AC068205.4, AC087521.2, AC087521.4, ALKBH3, SEC14L1P1, ALKBH3-AS1, AC087521.3, C11orf96, AC087521.1, ACCSL, ACCS, AC134775.1, EXT2, ALX4, AC010768.4, AC010768.3, CD82, AC010768.1, AC010768.2, RPL34P22, AC104010.1, LINC02704, TSPAN18-AS1, TSPAN18.
- chr21:46,598,604–46,665,124, 3 genes, copy number 5: S100B, PRMT2, DSTNP1.

Autosomal genes at a single copy (total copy number 1): 7,113. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
